Gene-level copy-number profile of tumor specimen TCGA-B5-A1N2-01A from TCGA case TCGA-B5-A1N2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 70.1 years (25,612 days).
Specimen TCGA-B5-A1N2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e5bdf2b3-a30c-4c47-876b-36547838410f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A1N2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4699326e-5588-44ea-b30c-5ec98903192d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,206; copy number 2: 19,354; copy number 3: 21,858; copy number 4: 11,202; copy number 5: 2,786; copy number 6: 1,930; copy number 7: 502; copy number 8: 286; copy number 9: 253; copy number 10: 395; copy number 11: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A1N2-01A-21D-A141-01): tumor purity 0.77, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,471 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:96,753,185–97,975,056, 12 genes, copy number 8: RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1.
- chr3:117,544,205–127,288,046, 207 genes, copy number 7 (broad region; genes not listed).
- chr3:161,600,438–198,222,513, 647 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr6:167,607–26,659,752, 500 genes, copy number 7–11 (broad region; genes not listed).
- chr6:37,630,679–37,819,218, 2 genes, copy number 9 (within-gene range 5–9): MDGA1, AL121574.1.
- chr6:37,832,922–37,833,185, 1 gene, copy number 9: RN7SL285P.
- chr8:124,920,428–131,040,909, 86 genes, copy number 7 (broad region; genes not listed).
- chr9:33,921,693–34,048,949, 1 gene, copy number 9 (within-gene range 4–9): UBAP2.
- chr9:33,968,071–34,343,711, 15 genes, copy number 9: OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2.

Autosomal genes at a single copy (total copy number 1): 1,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
